CPTAC case C3N-03880 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0900fe7b-1872-4214-bb2f-efb16234db23

Demographics
Sex at birth: male; Race: asian; Year of birth: 1942; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 76.1 years (27,786 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T1c; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,828 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,828 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.2 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 24; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 396 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 736 days (2.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 736 days (2.0 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,073 days (2.9 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,413 days (3.9 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,828 days (5.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 85 kg; Height: 170 cm; BMI: 29.41; DLCO (% of predicted): 85; FEV1/FVC before bronchodilator (%): 98; FEV1 before bronchodilator (% of reference): 71.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 108; Cigarettes per day: 40; Tobacco smoking onset year: 1964; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 58.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03880-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 80 mg; Time between clamping and freezing: 31 minutes; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03880-21: Section location: Left Upper Lobe; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-03880-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 83 mg; Time between clamping and freezing: 31 minutes; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03880-22: Section location: Left Upper Lobe; Percent tumor nuclei: 75; Percent necrosis: 3.
- Sample C3N-03880-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 95 mg; Time between clamping and freezing: 31 minutes; Time between excision and freezing: 18 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03880-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
